Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4643, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4643-01A (Primary Tumor).

DIAGNOSIS

TCGA-CJ-4643

(A) RIGHT KIDNEY AND ADRENAL GLAND:

RENAL CELL CARCINOMA, CONVENTIONAL (90% CLEAR CELLS AND 10% EOSINOPHILIC CELLS),

FURHMAN'S NUCLEAR GRADE 3.

TUMOR CONFINED TO KIDNEY.

TUMOR MEASURES 9.5 CM IN GREATEST DIMENSION.

Vascular, ureteral and soft tissue margins of resection free of tumor.

Adrenal gland with nodular cortical hyperplasia.

GROSS DESCRIPTION

(A) RIGHT KIDNEY AND ADRENAL GLAND - A nephrectomy specimen (22.0 x 13.5 x 6.3 cm) including the right kidney (13.0x 5.5 x 4.0 cm), a segment of the renal artery, the renal vein, two ureters (7.5 and 12.0 cm in length x approximately 0.4 cm in average diameter), and the adrenal gland (0.6 x 3.7 x 1.8 cm).

There is a 9.5 x 7.2 x 6.0 cm well-circumscribed tumor in the mid portion of the kidney. Centrally, the tumor has a myxoid appearance with a focus of calcification; the periphery is orange-yellow and slightly friable. There are no definitive areas of hemorrhage or necrosis. The tumor pushes onto the renal pelvis but does not invade it. There is no extension into the adipose tissue, renal sinus, renal vein, or Gerota's fascia.

The adjacent kidney parenchyma is unremarkable. The pelvicalyceal system is smooth and devoid of any lesions. One possible hilar lymph node measures 1.7 x 0.9 x 0.9 cm.

Serial cross sections of the adrenal gland show an enlarged cortex measuring 0.5 cm. The remainder of the adrenal gland is unremarkable.

Portions of tumor have been submitted for possible electron microscopy and to the tumor bank.

INK CODE: Black - Gerota's fascia and capsule nearest tumor.

SECTION CODE: A1, both ureters, renal artery, and renal vein margins, en face; A2, enlarged portion of adrenal gland; A3, kidney, representative sections; A4-A5, tumor within pelvis; A6-A8, tumor with inked capsule; A9-A10, tumor with adjacent kidney; A11, tumor; A12, representative sections of Gerota's fascia overlying tumor; A13, one possible lymph node; A14, tumor with sinus; A15, tumor with pelvis; A16, adrenal gland, representative section.

CLINICAL HISTORY

Right renal mass.

-----END OF REPORT-----

Source: NCI Genomic Data Commons file a0360a7e-c6c1-40ad-9084-4265d6dd1648 (TCGA-CJ-4643.1A9FA2BC-9999-404D-87B0-667935744BCE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).